Gene-level copy-number profile of tumor specimen TCGA-77-8144-01A from TCGA case TCGA-77-8144, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 70.6 years (25,796 days).
Specimen TCGA-77-8144-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.3bda9826-8810-41d4-9e80-e3df0266a518.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-8144-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c4b6e5a1-aced-4e78-8611-50c5a50ffc19

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 255; copy number 2: 11,889; copy number 3: 12,355; copy number 4: 29,856; copy number 5: 2,775; copy number 6: 2,270; copy number 7: 131; copy number 8: 23; copy number 9: 213; copy number 10: 8; copy number 12: 26; copy number 14: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-8144-01A-11D-2243-01): tumor purity 0.57, ploidy 3.6, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 256 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:51,438,792–51,665,048, 1 gene, copy number 14 (within-gene range 4–14): AC022433.1.
- chr5:51,886,688–61,304,811, 154 genes, copy number 9–14 (within-gene range 4–14) (broad region; genes not listed).
- chr7:97,437,518–99,050,831, 36 genes, copy number 9 (within-gene range 6–9): AP1S2P1, RN7SKP104, TAC1, ASNS, AC079781.5, AC005326.1, SNRPCP9, RPS3AP29, AC079781.1, AC079781.2, AC079781.4, AC079781.3, OR7E7P, MIR5692A1, MIR5692C2, OR7E38P, AC004967.2, AC004967.1, OCM2, RN7SL478P, LMTK2, BHLHA15, TECPR1, BRI3, BAIAP2L1, AC093799.1, RPS3AP26, PPIAP82, AC074121.1, NPTX2, RNU6-393P, TMEM130, TRRAP, MIR3609, AC004893.2, RNF14P3.
- chr7:102,813,230–103,989,658, 24 genes, copy number 9 (within-gene range 6–9): FBXL13, RNU6-1136P, RN7SKP198, LRRC17, NFE4, AC073127.1, ARMC10, CRYZP1, NAPEPLD, AC007683.1, RPL23AP95, AC007683.3, DPY19L2P2, S100A11P1, PMPCB, DNAJC2, PSMC2, RPS29P16, SLC26A5, Y_RNA, Y_RNA, AC005064.1, RELN, RN7SKP86.
- chr8:117,265,272–120,813,359, 41 genes, copy number 9–12: AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1, MRPL13, MTBP, SNTB1, NCAPGP1, AC104958.1, AC104958.2.

Autosomal genes at a single copy (total copy number 1): 253. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
